Gene-level copy-number profile of tumor specimen TCGA-WQ-A9G7-01A from TCGA case TCGA-WQ-A9G7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G3.
Specimen TCGA-WQ-A9G7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.69cb1b1c-8390-4f56-8813-4e3bb17da2b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WQ-A9G7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/66d309be-c956-4425-bbcb-ce2db9bf6e2c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 2: 14,994; copy number 3: 20,161; copy number 4: 12,192; copy number 5: 4,599; copy number 6: 6,196; copy number 7: 1,657.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WQ-A9G7-01A-11D-A36W-01): tumor purity 0.42, ploidy 3.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:36,819,276–37,050,846, 10 genes (within-gene range 0–3): LINC02033, AC105749.1, TRANK1, AC011816.1, RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1, MLH1, RPL29P11.
- chr4:85,990,007–86,594,625, 1 gene (within-gene range 0–2): MAPK10.
- chr4:86,336,318–86,815,171, 3 genes (within-gene range 0–2): RN7SKP96, MIR4452, PTPN13.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,657 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:86,547,078–88,685,204, 21 genes, copy number 7 (within-gene range 2–7): CLCA4, CDCA4P2, CLCA4-AS1, CLCA3P, CLCA4-AS1, SH3GLB1, AL049597.1, AL355981.1, SELENOF, HS2ST1, AL121989.1, AC093155.3, AC093155.2, AC093155.1, LINC01140, LINC02801, LMO4, LINC01364, RNA5SP52, PKN2-AS1, AL445437.1.
- chr1:118,614,333–118,713,678, 2 genes, copy number 7: PSMC1P12, AL139148.1.
- chr8:39,584,489–145,066,685, 1,634 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
